Somatic mutation profile of tumor specimen C3N-03063-02 (aliquot CPT0208910007) from CPTAC case C3N-03063, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 62.9 years (22,957 days).
Specimen C3N-03063-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16401bcb-9613-4d20-a914-68c1e9cebd71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03063-32 (Blood Derived Normal), aliquot CPT0208960002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb8b66f4-93f6-4030-86ca-eeb9faf73a5e

The open-access MAF lists 807 somatic variants for this specimen: 546 protein-altering or splice-affecting, 173 silent, 88 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 477, Silent 173, Intron 41, Nonsense Mutation 32, Frame Shift Del 14, 3'UTR 14, 5'UTR 12, Splice Region 10, RNA 9, 3'Flank 9, Splice Site 7, 5'Flank 3.

Variants (750 of 807; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 183/346 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 49/238 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAN | c.1338del p.T447Hfs*19 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | catalogued as COSV100719410; called by mutect2, pindel, varscan2
- ADCY10 | c.1795A>G p.I599V | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs746793741; called by muse, mutect2, varscan2
- AGBL1 | c.2075+2T>G p.X692_splice | Splice Site (SNP) | VAF 17/149 reads (11%) | catalogued as COSV101224052; called by muse, mutect2, varscan2
- AKR1C8P | c.164C>G p.A55G | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs782444149; called by muse, mutect2, varscan2
- AMPD1 | c.1452del p.N485Tfs*2 | Frame Shift Del (DEL) | VAF 21/188 reads (11%) | catalogued as COSV100814924; called by mutect2, pindel, varscan2
- ANTXR1 | c.1670G>T p.R557L | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.188); catalogued as rs185708952, COSV58013485, COSV58024333; called by muse, mutect2, varscan2
- APOB | c.726C>A p.S242R | Missense Mutation (SNP) | VAF 46/392 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.868); catalogued as COSV51945894; called by muse, mutect2, varscan2
- APOBR | c.3007C>A p.R1003S (on ENST00000431282; = p.R1012S on NM_018690.4) | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100112957; called by muse, mutect2, varscan2
- ASTN1 | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1177834978, COSV56065131; called by muse, mutect2
- ATP8B4 | c.3203G>T p.W1068L | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.606); catalogued as COSV99464450; called by muse, mutect2
- B3GAT2 | c.398C>A p.A133D | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV57775726; called by muse, mutect2, varscan2
- BCL9L | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs927232835; called by muse, mutect2
- BMP3 | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51083544; called by muse, mutect2, varscan2
- C10orf71 | c.3938C>A p.P1313Q | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs538923366; called by muse, mutect2, varscan2
- CACNA1I | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 45/345 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV60817153; called by muse, mutect2, varscan2
- CAPSL | c.153G>T p.M51I | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV101274240; called by muse, mutect2, varscan2
- CCDC141 | c.3291C>A p.H1097Q | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55383124; called by muse, mutect2, varscan2
- CCDC175 | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV55792446; called by muse, mutect2
- CCDC85A | c.920A>T p.K307M | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs1045637334, COSV101339524; called by muse, mutect2, varscan2
- CCK | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100588997; called by muse, mutect2, varscan2
- CDC42BPA | c.4762G>T p.G1588* (on ENST00000334218 / NM_001366019.2; = p.G1575* on NM_003607.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/154 reads (14%) | catalogued as COSV100507390; called by muse, varscan2
- CDH11 | c.2078G>T p.R693L | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV51754388, COSV99219492; called by muse, mutect2, varscan2
- CDH4 | c.744C>G p.H248Q | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as COSV64659999; called by muse, mutect2, varscan2
- CDH4 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as rs776562699, COSV64652419; called by muse, mutect2
- CEP131 | c.3177+8C>T | Splice Region (SNP) | VAF 24/237 reads (10%) | catalogued as COSV53957059; called by muse, mutect2, varscan2
- CFAP20DC | c.2025G>T p.Q675H (on ENST00000482387 / NM_001351530.2; = p.Q424H on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/312 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.367); catalogued as COSV55923060; called by muse, mutect2, varscan2
- CNTNAP2 | c.1294G>T p.G432C | Missense Mutation (SNP) | VAF 48/321 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.852); catalogued as COSV62166586; called by muse, mutect2, varscan2
- COL15A1 | c.3913T>C p.Y1305H | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767877646; called by muse, mutect2, varscan2
- COL1A2 | c.2467G>T p.G823C | Missense Mutation (SNP) | VAF 78/588 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM151747, HM090040; called by muse, mutect2, varscan2
- COL9A2 | c.420G>T p.G140= | Splice Region (SNP) | VAF 9/216 reads (4%) | catalogued as COSV65608047; called by muse, mutect2
- COLEC11 | c.356G>C p.R119P | Missense Mutation (SNP) | VAF 96/364 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV52595288; called by muse, mutect2, varscan2
- CORIN | c.953G>T p.C318F | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99903282; called by muse, mutect2, varscan2
- CPA1 | c.246C>A p.H82Q | Missense Mutation (SNP) | VAF 34/420 reads (8%) | SIFT tolerated (0.89); PolyPhen benign (0.052); catalogued as COSV50572141; called by muse, mutect2
- CR1 | c.3379G>T p.G1127C | Missense Mutation (SNP) | VAF 68/751 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV100887273; called by muse, mutect2, varscan2
- CTAGE8 | c.2168del p.P723Hfs*30 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs1247734966; called by mutect2, varscan2
- CXorf66 | c.310C>A p.Q104K | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.81); PolyPhen benign (0.03); catalogued as COSV65169696; called by muse, mutect2, varscan2
- DCAF4L2 | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60481886; called by muse, mutect2
- DEFB113 | c.53C>A p.P18Q | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV67143606; called by muse, mutect2, varscan2
- DLGAP3 | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV99332113; called by muse, mutect2, varscan2
- DNAH7 | c.6094G>C p.G2032R | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs933576639, COSV100417159; called by muse, mutect2, varscan2
- DOCK7 | c.1648G>T p.A550S | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.169); catalogued as rs146330198; called by muse, mutect2, varscan2
- DST | c.17140A>T p.I5714F (on ENST00000361203 / NM_001374722.1; = p.I3411F on NM_015548.5) | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1474265526; called by muse, mutect2, varscan2
- ELOVL6 | c.253A>G p.M85V | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV100165529; called by muse, mutect2, varscan2
- ERICH3 | c.2380G>T p.E794* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100445164; called by muse, mutect2, varscan2
- EYS | c.286C>A p.L96I | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV104416999; called by muse, mutect2, varscan2
- F2R | c.493G>T p.G165C | Missense Mutation (SNP) | VAF 101/399 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100058491; called by muse, mutect2, varscan2
- FCN2 | c.62G>C p.G21A | Missense Mutation (SNP) | VAF 62/354 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99391437; called by muse, mutect2, varscan2
- FGF6 | c.415G>T p.V139F | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV57403617; called by muse, mutect2, varscan2
- FGG | c.1205G>T p.W402L | Missense Mutation (SNP) | VAF 61/292 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as CM1310000; called by muse, mutect2, varscan2
- FLG | c.6477T>A p.D2159E | Missense Mutation (SNP) | VAF 64/1116 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs771980280; called by muse, mutect2
- FRMD5 | c.1321G>C p.E441Q | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.419); catalogued as rs772259917, COSV68720377; called by muse, mutect2
- FSIP2 | c.2560C>A p.Q854K | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as rs1394392350; called by muse, mutect2, varscan2
- GABRB3 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 32/564 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs1301259280, COSV54648717, COSV54671867; called by muse, mutect2
- GANC | c.1712G>T p.R571L | Missense Mutation (SNP) | VAF 36/141 reads (26%) | PolyPhen probably damaging (1); catalogued as COSV58807178; called by muse, mutect2, varscan2
- GINM1 | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.059); catalogued as rs977719157; called by muse, mutect2, varscan2
- GLB1 | c.1790C>T p.P597L | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM156656; called by muse, mutect2, varscan2
- GPR26 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.45); catalogued as rs770191184, COSV99501001; called by muse, mutect2
- GPR52 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 30/229 reads (13%) | catalogued as COSV52277832, COSV99267759; called by muse, mutect2, varscan2
- GPR65 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV99966051; called by muse, mutect2, varscan2
- GRIN2B | c.1232T>A p.L411Q | Missense Mutation (SNP) | VAF 363/697 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101663178; called by muse, mutect2, varscan2
- H2AC12 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 18/267 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.02); catalogued as rs778170423, COSV63617316; called by muse, mutect2
- HAO1 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 46/332 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV101113150; called by muse, mutect2, varscan2
- HOXA13 | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 111/524 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as COSV99763650; called by muse, mutect2, varscan2
- HOXD10 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.07); catalogued as COSV50895598; called by muse, mutect2, varscan2
- IL12A | c.346G>T p.V116L | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.96); catalogued as COSV59759236; called by muse, mutect2, varscan2
- ITGA2 | c.2215G>T p.E739* | Nonsense Mutation (SNP) | VAF 35/286 reads (12%) | catalogued as COSV56860603, COSV99670641; called by muse, mutect2, varscan2
- JAML | c.493G>A p.V165M (on ENST00000356289 / NM_001098526.2; = p.V155M on NM_153206.3) | Missense Mutation (SNP) | VAF 63/280 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.075); catalogued as rs753671009, COSV52626313; called by muse, mutect2, varscan2
- KCNH5 | c.2237C>A p.S746Y | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV59777599; called by muse, mutect2, varscan2
- KCNK9 | c.764G>C p.R255P | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.872); catalogued as COSV100271635, COSV57288884; called by muse, mutect2, varscan2
- KIAA0586 | c.-40G>T | Splice Region (SNP) | VAF 20/222 reads (9%) | catalogued as rs1273670039; called by muse, mutect2
- KIF2B | c.1385G>T p.R462L | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV52132439; called by muse, mutect2
- KMT2B | c.3532G>T p.D1178Y | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99720647; called by muse, mutect2, varscan2
- LAMA2 | c.3555G>C p.W1185C | Missense Mutation (SNP) | VAF 74/272 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); catalogued as rs774019483, COSV70345423; called by muse, mutect2, varscan2
- LHX5 | c.1004C>A p.A335D | Missense Mutation (SNP) | VAF 135/357 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs747350759; called by muse, mutect2, varscan2
- LIG1 | c.2521G>T p.V841L | Missense Mutation (SNP) | VAF 34/385 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99618907; called by muse, mutect2
- LRFN5 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV53242167, COSV53256587; called by muse, mutect2, varscan2
- LRIG1 | c.1688A>T p.H563L | Missense Mutation (SNP) | VAF 38/283 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV56239589; called by muse, mutect2, varscan2
- LRRC27 | c.368G>T p.R123I | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs537830662; called by muse, mutect2, varscan2
- LTBP1 | c.4274C>A p.A1425E (on ENST00000404816 / NM_206943.4; = p.A1099E on NM_000627.4) | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99698893; called by muse, mutect2, varscan2
- LYPD3 | c.730C>A p.P244T | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.131); catalogued as COSV54989254; called by muse, mutect2, varscan2
- MAGEA3 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 124/268 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as rs782715078, COSV100938978, COSV100939016; called by muse, mutect2, varscan2
- MAP4K1 | c.1354G>T p.A452S | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.855); catalogued as rs758428806; called by muse, mutect2, varscan2
- MFN1 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV54943060; called by muse, mutect2
- MROH7 | c.585G>T p.R195S | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as COSV59874679; called by muse, mutect2, varscan2
- MRPL46 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs1247490428; called by muse, mutect2
- MRPS15 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 23/261 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776496972, COSV64152121; called by muse, mutect2
- MUC17 | c.13443C>G p.I4481M | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV100074166; called by muse, mutect2
- MYBPC3 | c.2273G>T p.G758V | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM054783; called by muse, mutect2, varscan2
- MYH1 | c.1137T>A p.D379E | Missense Mutation (SNP) | VAF 54/267 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV99875021; called by muse, mutect2, varscan2
- MYH2 | c.2307C>G p.V769= | Splice Region (SNP) | VAF 32/419 reads (8%) | catalogued as COSV55438931, COSV99819202; called by muse, mutect2
- NAV2 | c.5407G>A p.V1803I (on ENST00000396087 / NM_001244963.2; = p.V1747I on NM_145117.5) | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.496); catalogued as rs1245383048, COSV60662482; called by muse, mutect2, varscan2
- NECTIN1 | c.974G>T p.R325L | Missense Mutation (SNP) | VAF 63/366 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV50598173; called by muse, mutect2, varscan2
- NEUROG2 | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.453); catalogued as rs769917988; called by muse, mutect2, varscan2
- NLRP3 | c.564C>G p.I188M | Missense Mutation (SNP) | VAF 52/443 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.03); catalogued as rs147631017; called by muse, mutect2, varscan2
- NPAS3 | c.928G>C p.G310R (on ENST00000356141 / NM_001164749.2; = p.G278R on NM_022123.3) | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60855996; called by muse, mutect2, varscan2
- NPAS4 | c.1093G>T p.A365S | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100215019; called by muse, mutect2, varscan2
- NRXN3 | c.2419C>T p.R807C (on ENST00000335750 / NM_001330195.2; = p.R434C on NM_004796.6) | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs145208693; called by muse, mutect2, varscan2
- OGA | c.2245G>T p.D749Y | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV63382066; called by muse, mutect2, varscan2
- OR10S1 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.602); catalogued as COSV73342923; called by muse, mutect2
- OR11G2 | c.662C>G p.P221R | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1371555961; called by muse, mutect2, varscan2
- OR13G1 | c.355C>A p.R119S | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV62944103, COSV62944701; called by muse, mutect2
- OR2C3 | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 36/387 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV63575463; called by muse, mutect2
- OR4C15 | c.1010C>A p.P337H (on ENST00000314644; = p.P283H on NM_001001920.2) | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs774055903, COSV58953325, COSV58954238, COSV58955502; called by muse, mutect2, varscan2
- OR5D18 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as rs538778668; called by muse, mutect2, varscan2
- PAM | c.1344G>T p.R448S | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV57221086; called by muse, mutect2, varscan2
- PCDH15 | c.5447C>T p.T1816I | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); catalogued as COSV57390824; called by muse, mutect2
- PCDHA5 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 199/776 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); catalogued as rs781935410, COSV65348896, COSV65349945; called by muse, mutect2, varscan2
- PCDHA9 | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 95/352 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.298); catalogued as rs775532292, COSV100969815, COSV65324024; called by muse, mutect2, varscan2
- PCDHAC2 | c.1264G>C p.V422L | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.351); catalogued as rs1288731231; called by muse, mutect2, varscan2
- PCDHB4 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.021); catalogued as COSV52020040; called by muse, mutect2, varscan2
- PDGFRB | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.539); catalogued as COSV55800972; called by muse, mutect2, varscan2
- PKLR | c.370C>A p.H124N | Missense Mutation (SNP) | VAF 73/605 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV61360528; called by muse, mutect2, varscan2
- PLCB4 | c.2203C>A p.R735S | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53798157, COSV99596637; called by muse, mutect2
- PLPPR4 | c.1000G>T p.D334Y | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV100926936; called by muse, mutect2, varscan2
- POTEH | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 61/949 reads (6%) | catalogued as COSV58879451; called by muse, mutect2
- PPARGC1A | c.1817G>A p.S606N | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as COSV53531494; called by muse, mutect2
- PPP4C | c.485G>T p.C162F | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1347649296; called by muse, mutect2, varscan2
- PRKDC | c.8186G>T p.R2729L | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100037775, COSV58051573, COSV58068122; called by muse, mutect2, varscan2
- PRR27 | c.87C>G p.D29E | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.399); catalogued as COSV100748777; called by muse, mutect2, varscan2
- PRSS37 | c.46T>A p.F16I | Missense Mutation (SNP) | VAF 37/279 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.049); catalogued as COSV63340070; called by muse, mutect2, varscan2
- PRTG | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 18/111 reads (16%) | catalogued as COSV66840476; called by muse, mutect2, varscan2
- PRUNE2 | c.5060C>A p.S1687Y | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV100945223; called by muse, mutect2, varscan2
- PRUNE2 | c.3277C>T p.R1093* | Nonsense Mutation (SNP) | VAF 26/243 reads (11%) | catalogued as rs750981306; called by muse, mutect2, varscan2
- RFPL4B | c.397G>C p.A133P | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV71437506; called by muse, mutect2, varscan2
- RPL7 | c.584A>G p.Y195C | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as rs1267585209; called by muse, mutect2, varscan2
- RTTN | c.1355A>G p.Y452C | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs754287552; called by muse, mutect2, varscan2
- RYR2 | c.1354G>T p.V452L | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.631); catalogued as COSV63701124; called by muse, mutect2, varscan2
- RYR2 | c.12676C>A p.P4226T | Missense Mutation (SNP) | VAF 32/382 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs1293881648, COSV63670303; called by muse, mutect2
- RYR2 | c.12677C>G p.P4226R | Missense Mutation (SNP) | VAF 35/386 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as COSV63660059; called by muse, mutect2
- SCG5 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100276923; called by muse, mutect2, varscan2
- SCN2A | c.4200T>G p.N1400K | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV99330036; called by muse, mutect2, varscan2
- SCN7A | c.2522G>T p.G841V | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.812); catalogued as COSV69270387; called by muse, mutect2, varscan2
- SDK2 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.752); catalogued as rs776371081, COSV66184147; called by muse, mutect2, varscan2
- SFMBT2 | c.2324C>T p.P775L | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs768081251; called by muse, mutect2, varscan2
- SFMBT2 | c.1640G>T p.R547M | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100738250; called by muse, mutect2, varscan2
- SGIP1 | c.2134G>T p.D712Y | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV52774084; called by muse, mutect2
- SH3TC2 | c.1254G>T p.Q418H | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.087); catalogued as rs146997517; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC29A3 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 64/397 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs368939297; called by muse, mutect2, varscan2
- SLC2A12 | c.229C>T p.H77Y | Missense Mutation (SNP) | VAF 69/269 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV51602956; called by muse, mutect2, varscan2
- SLC30A10 | c.1304C>A p.P435H | Missense Mutation (SNP) | VAF 68/303 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.533); catalogued as COSV104415222, COSV63071457; called by muse, mutect2, varscan2
- SLC34A3 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs387907514; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC5A6 | c.91G>T p.V31L | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as COSV60159699; called by muse, mutect2, varscan2
- SLIT3 | c.3296C>A p.T1099N | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.319); catalogued as rs747954140; called by mutect2, varscan2
- SNAI2 | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50078590; called by muse, mutect2, varscan2
- SOCS5 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 13/288 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV60603916, COSV60604974; called by muse, mutect2
- SP8 | c.343G>A p.A115T (on ENST00000361443 / NM_198956.4; = p.A133T on NM_182700.6) | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.226); catalogued as rs1414718744; called by muse, varscan2
- SPAG7 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV52777019; called by muse, mutect2, varscan2
- SPTA1 | c.5731C>A p.P1911T | Missense Mutation (SNP) | VAF 33/360 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as COSV100934660; called by muse, mutect2
- SPTA1 | c.4159C>A p.R1387S | Missense Mutation (SNP) | VAF 52/544 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63749356; called by muse, mutect2
- STYXL2 | c.1387G>T p.G463C | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.487); catalogued as COSV54806575; called by muse, mutect2, varscan2
- SWT1 | c.734A>G p.Q245R | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs148938329; called by muse, mutect2, varscan2
- SYNE1 | c.14204A>G p.Q4735R (on ENST00000367255 / NM_182961.4; = p.Q4664R on NM_033071.3) | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.889); catalogued as rs780911809; called by muse, mutect2, varscan2
- SYNE1 | c.26G>C p.R9P | Missense Mutation (SNP) | VAF 171/530 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); catalogued as COSV54972806; called by muse, mutect2, varscan2
- SYT14 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 34/313 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV55057732; called by muse, mutect2, varscan2
- TBCEL | c.1253A>G p.Y418C | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as rs753069098; called by muse, mutect2
- TEX14 | c.2359G>A p.A787T (on ENST00000240361 / NM_001201457.2; = p.A781T on NM_031272.5) | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs146761365; called by muse, mutect2, varscan2
- TP53TG5 | c.709C>A p.R237S | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65578252; called by muse, mutect2, varscan2
- TPGS2 | c.254-1G>A p.X85_splice | Splice Site (SNP) | VAF 9/93 reads (10%) | catalogued as rs780607810; called by muse, mutect2
- TPO | c.438C>A p.C146* | Nonsense Mutation (SNP) | VAF 56/373 reads (15%) | catalogued as rs1483767054; called by muse, mutect2, varscan2
- TRIML2 | c.872C>A p.A291D | Missense Mutation (SNP) | VAF 50/259 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58715621; called by muse, mutect2, varscan2
- TSEN34 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 31/378 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs373921569; called by muse, mutect2
- UNC5C | c.561G>C p.Q187H | Missense Mutation (SNP) | VAF 61/395 reads (15%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.522); catalogued as rs1446846682, COSV71662935; called by muse, mutect2, varscan2
- USH1G | c.514C>G p.R172G | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs199941325; called by muse, mutect2, varscan2
- USH2A | c.13477C>T p.R4493C | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs144543286; called by muse, mutect2, varscan2
- USH2A | c.9293G>A p.S3098N | Missense Mutation (SNP) | VAF 55/311 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs201393158; called by muse, mutect2, varscan2
- USP34 | c.3543-1G>T p.X1181_splice | Splice Site (SNP) | VAF 35/132 reads (27%) | catalogued as COSV101277136; called by muse, mutect2, varscan2
- VARS1 | c.1852C>T p.R618W | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs555534146; called by muse, mutect2
- VCAN | c.8332C>A p.P2778T | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as COSV99424578; called by muse, mutect2, varscan2
- VPS9D1 | c.1876C>T p.R626W | Missense Mutation (SNP) | VAF 118/303 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs771610159, COSV66995190; called by muse, mutect2, varscan2
- WDR53 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV60283518; called by muse, mutect2, varscan2
- XPO5 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.503); catalogued as rs763869190; called by muse, mutect2, varscan2
- ZNF568 | c.1240C>G p.Q414E | Missense Mutation (SNP) | VAF 13/219 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as rs1046813444; called by muse, mutect2
- ZNF605 | c.1850A>G p.Y617C | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as rs971177328; called by muse, mutect2, varscan2
- ZNF800 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as rs201908392; called by muse, mutect2, varscan2
- ZNF804A | c.871G>T p.V291F | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as COSV56443173, COSV56467708; called by muse, mutect2, varscan2
- ZSCAN12 | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV63010550; called by muse, mutect2
- A1CF | c.89G>A p.S30N | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA13 | c.4321G>A p.V1441M | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ABCC1 | c.1948A>T p.T650S | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- AC127029.3 | c.542C>A p.S181Y | Missense Mutation (SNP) | VAF 38/360 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- ACSM2A | c.751C>A p.L251M (on ENST00000219054; = p.L172M on NM_001308169.2) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- ACSM6 | c.381C>G p.I127M | Missense Mutation (SNP) | VAF 38/357 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.326); called by muse, mutect2
- ADAMTS16 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- ADAMTS20 | c.5621C>A p.S1874Y | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- ADAMTS6 | c.17A>T p.K6M | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- ADAP1 | c.212A>T p.E71V | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ADGRL2 | c.2185A>T p.T729S (on ENST00000370717 / NM_001366005.1; = p.T716S on NM_012302.4) | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ADGRL3 | c.4615C>A p.H1539N (on ENST00000506720 / NM_001322402.2; = p.H1428N on NM_015236.6) | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.085); called by muse, varscan2
- AGPS | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AGRN | c.4844G>C p.C1615S | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- AHNAK2 | c.8133G>T p.Q2711H | Missense Mutation (SNP) | VAF 169/523 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AHNAK2 | c.3071C>T p.S1024F | Missense Mutation (SNP) | VAF 234/752 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- AKAP6 | c.2145del p.L717* | Frame Shift Del (DEL) | VAF 23/142 reads (16%) | called by mutect2, pindel, varscan2
- AKT3 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 9/219 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.463); called by muse, mutect2
- ALOX5AP | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.751); called by muse, mutect2
- ALPG | c.795C>A p.Y265* | Nonsense Mutation (SNP) | VAF 49/359 reads (14%) | called by muse, mutect2, varscan2
- AMN1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 104/466 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ANK2 | c.1907C>G p.A636G | Missense Mutation (SNP) | VAF 25/279 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ANK2 | c.6890C>A p.T2297N | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- APEX1 | c.284A>T p.Q95L | Missense Mutation (SNP) | VAF 46/271 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ARAP2 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARFGEF2 | c.153-2A>T p.X51_splice | Splice Site (SNP) | VAF 139/591 reads (24%) | called by muse, mutect2, varscan2
- ARHGEF28 | c.2531A>G p.E844G | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); called by muse, mutect2
- ATG14 | c.1405A>T p.S469C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- ATP4A | c.728C>G p.T243R | Missense Mutation (SNP) | VAF 113/390 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP8B3 | c.860C>T p.T287I | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- B3GNT3 | c.976T>A p.S326T | Missense Mutation (SNP) | VAF 78/239 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- BIRC6 | c.11782G>T p.V3928L | Missense Mutation (SNP) | VAF 40/303 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BIRC6 | c.12125A>G p.E4042G | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.381); called by muse, mutect2
- BNC1 | c.728T>A p.M243K | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- BPIFB3 | c.766G>C p.G256R | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BRDT | c.509A>T p.K170I | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BRINP1 | c.1248C>A p.H416Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- BTN2A2 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 61/307 reads (20%) | called by muse, mutect2, varscan2
- C2CD2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 48/172 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1G | c.2497C>A p.L833M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- CAMSAP1 | c.441G>C p.M147I | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CARMIL2 | c.687+1G>T p.X229_splice | Splice Site (SNP) | VAF 94/225 reads (42%) | called by muse, mutect2, varscan2
- CBLB | c.2821G>T p.G941* | Nonsense Mutation (SNP) | VAF 36/361 reads (10%) | called by muse, mutect2
- CCDC150 | c.1960G>T p.D654Y | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- CCDC158 | c.1738C>A p.Q580K | Missense Mutation (SNP) | VAF 86/313 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CCDC173 | c.380A>T p.E127V | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2
- CCDC8 | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- CCDC83 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CCM2L | c.1052C>A p.P351Q | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- CD300LB | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 79/203 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CD93 | c.1667C>G p.S556C | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- CDC42BPA | c.4763G>T p.G1588V (on ENST00000334218 / NM_001366019.2; = p.G1575V on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CDC42BPB | c.1522G>C p.E508Q | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CDH9 | c.1841G>T p.G614V | Missense Mutation (SNP) | VAF 81/241 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDHR1 | c.1971G>T p.Q657H | Missense Mutation (SNP) | VAF 57/249 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CDK7 | c.608T>A p.L203* | Nonsense Mutation (SNP) | VAF 42/340 reads (12%) | called by muse, mutect2, varscan2
- CDKN1C | c.331G>T p.V111F | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- CELF4 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- CEP164 | c.1723G>T p.V575L | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP63 | c.1267G>T p.E423* | Nonsense Mutation (SNP) | VAF 37/141 reads (26%) | called by muse, mutect2, varscan2
- CFAP44 | c.4784A>C p.N1595T | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- CFAP44 | c.4345G>C p.E1449Q | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.96); PolyPhen benign (0.13); called by muse, mutect2
- CFAP47 | c.7067G>T p.W2356L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- CHAC1 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 61/320 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CHD1L | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.298); called by muse, mutect2
- CHD8 | c.1605del p.I536Sfs*4 (on ENST00000646647 / NM_001170629.2; = p.I257Sfs*4 on NM_020920.4) | Frame Shift Del (DEL) | VAF 12/112 reads (11%) | called by mutect2, pindel
- CHM | c.41T>C p.I14T | Missense Mutation (SNP) | VAF 118/284 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- CHST1 | c.697G>T p.V233F | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CIT | c.3714+3G>C | Splice Region (SNP) | VAF 10/228 reads (4%) | called by muse, mutect2
- CIZ1 | c.1634G>T p.G545V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CLCN5 | c.1831A>G p.I611V | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLPS | c.39del p.V14Wfs*22 | Frame Shift Del (DEL) | VAF 14/110 reads (13%) | called by mutect2, pindel, varscan2
- CNTNAP2 | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 114/432 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- CNTNAP4 | c.2863C>A p.Q955K | Missense Mutation (SNP) | VAF 104/335 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL10A1 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 69/228 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- COL12A1 | c.1924G>T p.E642* | Nonsense Mutation (SNP) | VAF 33/112 reads (29%) | called by muse, mutect2, varscan2
- COL18A1 | c.3697G>C p.G1233R (on ENST00000359759 / NM_130444.3; = p.G998R on NM_030582.4) | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- COL1A1 | c.2233A>G p.R745G | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL20A1 | c.2719C>A p.L907I | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- COL6A3 | c.4756A>G p.I1586V | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- COL6A5 | c.63C>A p.S21R | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- COL6A5 | c.3599A>G p.D1200G | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- COQ8A | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 22/552 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- CORO6 | c.330G>C p.Q110H | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.028); called by muse, mutect2
- CPA5 | c.853A>T p.S285C | Missense Mutation (SNP) | VAF 112/317 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- CPAMD8 | c.4840G>T p.G1614W (on ENST00000651564; = p.G1567W on NM_015692.5) | Missense Mutation (SNP) | VAF 67/251 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPN1 | c.442C>A p.L148I | Missense Mutation (SNP) | VAF 154/426 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- CPSF4L | c.431_432insT p.R145Qfs*? | Frame Shift Ins (INS) | VAF 22/122 reads (18%) | called by mutect2, pindel, varscan2
- CSPP1 | c.1101G>T p.M367I (on ENST00000676605; = p.M326I on NM_024790.6) | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CSTF1 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- CYP11B2 | c.940G>C p.G314R | Missense Mutation (SNP) | VAF 62/489 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP2C18 | c.1048G>T p.A350S | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DDX10 | c.1994A>T p.K665M | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- DLGAP3 | c.1111C>A p.P371T | Missense Mutation (SNP) | VAF 47/296 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH12 | c.4559C>T p.T1520I (on ENST00000351747; = p.T1543I on NM_001366028.2) | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAJB4 | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- DNAJC5B | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 18/472 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); called by muse, mutect2
- DNAJC6 | c.2500A>G p.R834G | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK1 | c.5392G>A p.V1798I | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPH6 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DPPA2 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- EEF2K | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- EHMT2 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- EIF3K | c.616G>C p.D206H | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2
- EML5 | c.5140G>A p.E1714K (on ENST00000380664; = p.E1722K on NM_183387.3) | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.403); called by muse, mutect2
- EPHA3 | c.788A>G p.Y263C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- EPHA3 | c.2546G>T p.C849F | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHB6 | c.1464G>A p.V488= | Splice Region (SNP) | VAF 31/370 reads (8%) | called by muse, mutect2
- EPHX3 | c.348G>C p.Q116H | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERBB4 | c.3760C>A p.Q1254K | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ERCC6L2 | c.1648G>T p.D550Y | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- FAM120A | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.017); called by muse, mutect2
- FAM169A | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.491); called by muse, mutect2
- FBXL16 | c.1384C>A p.P462T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- FBXO38 | c.2098G>T p.V700F | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- FGF11 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- FHDC1 | c.2816G>T p.W939L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLG | c.11023G>T p.D3675Y | Missense Mutation (SNP) | VAF 79/979 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2
- FMO1 | c.817C>A p.P273T | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- FOXC2 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 46/120 reads (38%) | called by muse, mutect2, varscan2
- FOXF1 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXN2 | c.551G>A p.G184D | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FREM3 | c.5621T>C p.M1874T | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GALNT13 | c.1395+9_1395+10del | Splice Region (DEL) | VAF 28/203 reads (14%) | called by pindel, varscan2
- GATA5 | c.431C>A p.A144D | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- GCKR | c.1589C>T p.S530F | Missense Mutation (SNP) | VAF 15/422 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, mutect2
- GFI1 | c.379C>A p.L127M | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- GHRHR | c.1105-1G>T p.X369_splice | Splice Site (SNP) | VAF 77/537 reads (14%) | called by muse, mutect2, varscan2
- GIMAP6 | c.127C>A p.L43I | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.669); called by muse, mutect2
- GNL1 | c.730C>A p.Q244K | Missense Mutation (SNP) | VAF 27/432 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- GNS | c.879del p.W293Cfs*46 | Frame Shift Del (DEL) | VAF 92/298 reads (31%) | called by mutect2, pindel, varscan2
- GOLGA6C | c.690C>G p.D230E | Missense Mutation (SNP) | VAF 79/566 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GPM6A | c.258C>G p.Y86* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | called by mutect2, varscan2
- GPR137B | c.822C>A p.Y274* | Nonsense Mutation (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- GPR31 | c.860C>G p.P287R | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.49); called by muse, varscan2
- GRAMD2A | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GRM1 | c.1607T>C p.I536T | Missense Mutation (SNP) | VAF 113/299 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GSG1 | c.653C>T p.A218V (on ENST00000651961 / NM_001080555.4; = p.G223= on NM_031289.5) | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HCRTR2 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 92/373 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- HEMGN | c.367T>A p.S123T | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- HEPACAM | c.67C>A p.L23I | Missense Mutation (SNP) | VAF 85/398 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- HEXA | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 52/306 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HGS | c.2053A>C p.I685L | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by mutect2, varscan2
- HMCN1 | c.3288G>T p.E1096D | Missense Mutation (SNP) | VAF 62/509 reads (12%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- HPS6 | c.52G>C p.G18R | Missense Mutation (SNP) | VAF 112/402 reads (28%) | SIFT tolerated (0.95); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- HSF1 | c.43G>T p.V15F | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HTT | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 39/187 reads (21%) | called by muse, mutect2, varscan2
- IGLJ6 | c.43G>T p.G15C | Missense Mutation (SNP) | VAF 71/359 reads (20%) | PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- IGLV1-50 | c.45A>G p.T15= | Splice Region (SNP) | VAF 59/252 reads (23%) | called by muse, mutect2, varscan2
- IMPG2 | c.3606G>C p.M1202I | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- INTS1 | c.6072G>T p.E2024D | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- INTS7 | c.419A>T p.H140L | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IQGAP3 | c.1366G>T p.A456S | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.985); called by muse, mutect2
- ITFG2 | c.1240G>T p.D414Y | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- KARS1 | c.62A>G p.N21S | Missense Mutation (SNP) | VAF 180/514 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH8 | c.1140G>C p.M380I | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KCNMA1 | c.3684G>T p.Q1228H (on ENST00000286628 / NM_001161352.2; = p.Q1170H on NM_002247.4) | Missense Mutation (SNP) | VAF 54/421 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCNQ2 | c.1780G>T p.G594W (on ENST00000359125 / NM_172107.4; = p.G566W on NM_004518.6) | Missense Mutation (SNP) | VAF 108/546 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNV2 | c.1172C>A p.A391E | Missense Mutation (SNP) | VAF 142/468 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCTD8 | c.520A>G p.S174G | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KDM6B | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 66/274 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- KIAA1755 | c.2210C>A p.S737Y | Missense Mutation (SNP) | VAF 71/240 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- KIF16B | c.512A>G p.N171S | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- KIR2DL3 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 102/418 reads (24%) | called by muse, mutect2, varscan2
- KLC3 | c.-8-4C>G | Splice Region (SNP) | VAF 73/237 reads (31%) | called by muse, mutect2, varscan2
- KLHL10 | c.120C>A p.D40E | Missense Mutation (SNP) | VAF 63/268 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL29 | c.2593T>C p.C865R | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KMT2B | c.2076G>T p.E692D | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KNDC1 | c.1948C>A p.P650T | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- KRT16 | c.795G>T p.Q265H | Missense Mutation (SNP) | VAF 105/419 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- KRT32 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 46/371 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRT4 | c.248_249insAGGCTTTGGTGCCGGCGGCTTCGGAGCTGGTTTCGGCACTGG p.G86_G87insAGGFGAGFGTGGFG | In Frame Ins (INS) | VAF 24/158 reads (15%) | called by mutect2, varscan2*
- KRT85 | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.137); called by muse, mutect2
- KRTCAP3 | c.119A>T p.H40L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- LAMA5 | c.4110G>T p.W1370C | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- LAX1 | c.1107C>G p.D369E | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- LCP2 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- LDB2 | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LEFTY1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 32/424 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2
- LIMD1 | c.1085A>T p.Q362L | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- LMAN2 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- LMOD2 | c.88C>A p.L30M | Missense Mutation (SNP) | VAF 51/369 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC30 | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 33/337 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LRRC63 | c.878G>T p.R293L | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- LRRFIP1 | c.1586G>T p.C529F (on ENST00000392000 / NM_001137552.2; = p.C505F on NM_004735.4) | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2
- LRRIQ3 | c.1147C>A p.Q383K | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LYPD3 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- MAML1 | c.1932G>T p.Q644H | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- MAML1 | c.1933C>T p.Q645* | Nonsense Mutation (SNP) | VAF 53/259 reads (20%) | called by muse, mutect2, varscan2
- MATN4 | c.1577del p.G526Afs*29 (on ENST00000372754; = p.G485Afs*29 on NM_003833.4) | Frame Shift Del (DEL) | VAF 41/288 reads (14%) | called by mutect2, pindel, varscan2
- MCOLN2 | c.1010C>A p.T337N | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MEMO1 | c.635C>A p.S212Y | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- METTL8 | c.178G>C p.A60P | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.548); called by muse, mutect2
- MFN1 | c.1216G>T p.A406S | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- MIB1 | c.847G>T p.G283* | Nonsense Mutation (SNP) | VAF 42/301 reads (14%) | called by muse, mutect2, varscan2
- MID2 | c.1265A>C p.H422P | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- MROH2B | c.4393C>A p.L1465I | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- MRPL32 | c.436G>T p.G146W | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTR | c.517G>T p.V173F | Missense Mutation (SNP) | VAF 136/411 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- MTR | c.2954G>T p.R985L | Missense Mutation (SNP) | VAF 38/374 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by mutect2, varscan2
- MUC16 | c.41229C>G p.D13743E | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MUC22 | c.3359C>A p.T1120N | Missense Mutation (SNP) | VAF 54/537 reads (10%) | SIFT deleterious (0.01); called by muse, mutect2
- MUC5B | c.8267G>T p.G2756V | Missense Mutation (SNP) | VAF 69/326 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- MXRA5 | c.6512C>A p.S2171* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- MYH1 | c.1138G>T p.G380C | Missense Mutation (SNP) | VAF 53/264 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- MYH13 | c.1249C>T p.Q417* | Nonsense Mutation (SNP) | VAF 37/126 reads (29%) | called by muse, mutect2, varscan2
- MYLK | c.5219T>A p.M1740K | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- NADK | c.548del p.G183Efs*30 | Frame Shift Del (DEL) | VAF 62/373 reads (17%) | called by mutect2, pindel, varscan2
- NALCN | c.4291T>G p.Y1431D | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NCAN | c.849G>T p.Q283H | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NCKAP5L | c.3481G>T p.A1161S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEU4 | c.394G>C p.A132P (on ENST00000391969 / NM_001167602.3; = p.A144P on NM_080741.4) | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- NFX1 | c.1682G>A p.C561Y | Missense Mutation (SNP) | VAF 70/172 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NHSL1 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NID2 | c.3026C>A p.P1009Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.047); called by muse, mutect2
- NLRP5 | c.890G>T p.R297I | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- NRBP2 | c.1382-6C>A | Splice Region (SNP) | VAF 98/226 reads (43%) | called by muse, mutect2, varscan2
- NRCAM | c.3501G>T p.Q1167H (on ENST00000379028 / NM_001371124.1; = p.Q1046H on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- NRIP1 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NRXN1 | c.4071G>C p.E1357D | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUMBL | c.268G>T p.V90L | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- NUP205 | c.2337G>T p.Q779H | Missense Mutation (SNP) | VAF 103/333 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- NXPE1 | c.554C>G p.P185R (on ENST00000424269; = p.P43R on NM_152315.5) | Missense Mutation (SNP) | VAF 65/291 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NXPH1 | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NYNRIN | c.1486G>T p.G496W | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- OBSCN | c.11451dup p.T3818Hfs*7 | Frame Shift Ins (INS) | VAF 85/300 reads (28%) | called by mutect2, pindel, varscan2
- OCA2 | c.2443C>G p.P815A | Missense Mutation (SNP) | VAF 87/464 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- OCA2 | c.2039C>A p.A680E | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- OGDHL | c.1506G>T p.E502D | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2AG1 | c.600T>A p.Y200* | Nonsense Mutation (SNP) | VAF 77/237 reads (32%) | called by muse, mutect2, varscan2
- OR2T33 | c.380C>G p.P127R | Missense Mutation (SNP) | VAF 128/603 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- OR4C11 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OR4C3 | c.590T>G p.V197G | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- OR4C46 | c.557C>A p.A186D | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- OR4D5 | c.836C>A p.T279N | Missense Mutation (SNP) | VAF 49/262 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- OR52E2 | c.29A>T p.H10L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2
- OR6P1 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 19/190 reads (10%) | called by muse, mutect2, varscan2
- OR6Y1 | c.230G>C p.W77S | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- OXCT1 | c.437G>T p.R146L | Missense Mutation (SNP) | VAF 59/431 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCDHA1 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 189/807 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA10 | c.2339T>A p.V780E | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PCDHB7 | c.1961C>A p.A654D | Missense Mutation (SNP) | VAF 134/1456 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- PCDHGA3 | c.1283del p.G428Efs*15 | Frame Shift Del (DEL) | VAF 25/154 reads (16%) | called by mutect2, pindel, varscan2
- PCDHGA4 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PCSK5 | c.133G>T p.G45W | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCSK5 | c.5492C>A p.T1831K | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDGFRA | c.113T>A p.V38D | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- PEX5 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 38/594 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.41); called by muse, mutect2
- PGA3 | c.38C>G p.S13C | Missense Mutation (SNP) | VAF 49/692 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- PHLPP1 | c.2986A>T p.N996Y | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PIP4K2A | c.1162G>T p.V388L | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PIWIL4 | c.1746G>C p.L582F | Missense Mutation (SNP) | VAF 32/601 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2
- PKHD1 | c.9566C>A p.P3189Q | Missense Mutation (SNP) | VAF 48/457 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PKNOX2 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- PLXNA2 | c.3730G>T p.A1244S | Missense Mutation (SNP) | VAF 48/414 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- POU4F1 | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- PPP4R2 | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
- PSMA2 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 54/299 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- PTGER3 | c.1156G>T p.G386W | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAB43 | c.553G>T p.G185W | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAB5A | c.223del p.D75Ifs*11 | Frame Shift Del (DEL) | VAF 14/142 reads (10%) | called by mutect2, pindel, varscan2
- RANBP2 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 36/699 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by muse, mutect2
- RARRES1 | c.568C>A p.L190I | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RASSF2 | c.527A>G p.Y176C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBBP8 | c.164G>C p.R55T | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM6 | c.1923G>C p.E641D | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.152); called by muse, mutect2
- RELN | c.3923G>T p.G1308V | Missense Mutation (SNP) | VAF 67/449 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RFX6 | c.2455A>T p.N819Y | Missense Mutation (SNP) | VAF 69/260 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- RFX8 | c.1034G>A p.R345K (on ENST00000646446; = p.R274K on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RGS1 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RIN3 | c.1548G>T p.Q516H | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- RNF175 | c.696G>C p.Q232H | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); called by muse, mutect2
- RNF180 | c.814C>A p.Q272K | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- ROS1 | c.4954A>G p.T1652A | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPTOR | c.495G>T p.W165C | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RSBN1 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.831); called by muse, mutect2
- RSBN1 | c.48G>T p.E16D | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.111); called by muse, mutect2
- RUFY4 | c.623C>A p.P208H | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- RYR1 | c.11999T>A p.M4000K | Missense Mutation (SNP) | VAF 169/915 reads (18%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SALL2 | c.1127G>T p.R376L | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SARS1 | c.407G>C p.G136A | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- SCAF11 | c.2510A>G p.N837S | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- SCAMP1 | c.131G>C p.R44T | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- SCAP | c.1192A>T p.T398S | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); called by muse, mutect2
- SEL1L | c.1820A>T p.E607V | Missense Mutation (SNP) | VAF 42/241 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SEMA6A | c.1988C>A p.A663D | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEPTIN4 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SERPINA1 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEZ6L | c.1648dup p.R550Pfs*11 | Frame Shift Ins (INS) | VAF 42/163 reads (26%) | called by mutect2, pindel, varscan2
- SFMBT2 | c.1641G>T p.R547S | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SH3TC1 | c.2549C>T p.S850F | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- SHANK1 | c.4589C>A p.S1530Y | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- SHANK3 | c.2740C>T p.R914W | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by mutect2, varscan2
- SI | c.76G>C p.A26P | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SLAIN2 | c.412A>G p.K138E | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.96); PolyPhen benign (0.121); called by muse, mutect2
- SLC22A12 | c.541C>A p.L181I | Missense Mutation (SNP) | VAF 124/429 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SLC25A13 | c.697A>G p.I233V | Missense Mutation (SNP) | VAF 113/420 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC44A1 | c.1148A>T p.Y383F | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SLC7A4 | c.1454T>C p.M485T | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- SLC9A9 | c.1840C>A p.Q614K | Missense Mutation (SNP) | VAF 90/297 reads (30%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLITRK3 | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- SLITRK4 | c.1693C>T p.Q565* | Nonsense Mutation (SNP) | VAF 12/192 reads (6%) | called by muse, mutect2
- SNCB | c.329C>A p.P110H | Missense Mutation (SNP) | VAF 78/550 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- SORT1 | c.1970A>G p.Y657C | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SPAG11B | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 50/302 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.983); called by muse, varscan2
- SPEG | c.4680G>T p.Q1560H | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SRD5A1 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 91/262 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SSU72P8 | c.507A>T p.E169D | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT tolerated (0.97); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- STARD13 | c.860G>T p.S287I (on ENST00000336934 / NM_001243476.3; = p.S169I on NM_052851.3) | Missense Mutation (SNP) | VAF 124/472 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- STK35 | c.1148G>A p.G383E | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STX19 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYNC | c.1104C>G p.I368M | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- TAS1R2 | c.2462G>T p.R821L | Missense Mutation (SNP) | VAF 95/649 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TAS1R3 | c.1356G>T p.M452I | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TBATA | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TCERG1L | c.684C>G p.N228K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- TFR2 | c.976G>T p.G326* | Nonsense Mutation (SNP) | VAF 50/137 reads (36%) | called by muse, mutect2, varscan2
- THSD4 | c.834G>T p.Q278H | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- THSD7B | c.1193G>A p.C398Y | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMCC2 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 93/408 reads (23%) | called by muse, mutect2, varscan2
- TMEM132A | c.1028T>A p.L343Q (on ENST00000453848 / NM_178031.3; = p.L344Q on NM_017870.4) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMEM176A | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- TMEM200B | c.782T>A p.L261Q | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM245 | c.753G>A p.M251I | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- TMEM270 | c.10C>A p.L4I | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM52B | c.284G>A p.S95N (on ENST00000381923 / NM_001079815.1; = p.S75N on NM_153022.4) | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2
- TMEM63C | c.934G>T p.D312Y | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- TMPRSS13 | c.436A>T p.T146S | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TNKS1BP1 | c.2276G>T p.G759V | Missense Mutation (SNP) | VAF 84/351 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.324); called by muse, varscan2
- TNNI3K | c.2294G>T p.S765I | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- TPTE | c.1339T>C p.S447P (on ENST00000618007 / NM_199261.4; = p.S429P on NM_199259.4) | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); called by muse, mutect2
- TRDV1 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- TRIM21 | c.319G>T p.G107W | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM24 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.041); called by muse, mutect2
- TRIM43 | c.622A>G p.I208V | Missense Mutation (SNP) | VAF 89/389 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- TRIM49 | c.829G>T p.G277* | Nonsense Mutation (SNP) | VAF 23/93 reads (25%) | called by mutect2, varscan2
- TRIM49 | c.359A>T p.E120V | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- TTC21B | c.755A>T p.Q252L | Missense Mutation (SNP) | VAF 90/355 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.25817_25827del p.T8606Ifs*22 (on ENST00000591111; = p.T7679Ifs*22 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- UBA1 | c.3103G>T p.V1035L | Missense Mutation (SNP) | VAF 75/229 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC5D | c.645C>G p.N215K | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- USH2A | c.2042A>T p.Y681F | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- USP15 | c.2620del p.R874Afs*4 (on ENST00000280377 / NM_001351159.2; = p.R845Afs*4 on NM_006313.3 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 48/144 reads (33%) | called by mutect2, pindel, varscan2
- VN1R5 | c.839C>A p.T280K | Missense Mutation (SNP) | VAF 84/267 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- VRK1 | c.1159+2T>G p.X387_splice | Splice Site (SNP) | VAF 49/442 reads (11%) | called by muse, mutect2, varscan2
- WDR64 | c.2974A>G p.R992G | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- WFS1 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 52/301 reads (17%) | called by muse, mutect2, varscan2
- WIPI2 | c.454A>T p.R152W | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- XKR7 | c.476C>A p.P159H | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.428); called by muse, mutect2
- YTHDF2 | c.1193A>G p.Y398C | Missense Mutation (SNP) | VAF 24/285 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.349); called by muse, mutect2
- ZBTB1 | c.1471del p.E491Kfs*10 | Frame Shift Del (DEL) | VAF 31/180 reads (17%) | called by mutect2, pindel, varscan2
- ZBTB14 | c.694G>T p.G232W | Missense Mutation (SNP) | VAF 9/203 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2
- ZBTB9 | c.160G>T p.V54L | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFAND6 | c.166A>T p.S56C | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- ZFYVE26 | c.5845G>T p.A1949S | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZFYVE9 | c.1990T>A p.L664I | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF211 | c.895A>C p.S299R (on ENST00000347302 / NM_198855.4; = p.S312R on NM_006385.5) | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ZNF221 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 39/283 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- ZNF229 | c.2111G>T p.R704M | Missense Mutation (SNP) | VAF 77/431 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF382 | c.1370T>G p.I457S | Missense Mutation (SNP) | VAF 60/294 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ZNF654 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF691 | c.479G>T p.R160L (on ENST00000372502; = p.R129L on NM_015911.3) | Missense Mutation (SNP) | VAF 50/329 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ZNF701 | c.697G>C p.A233P (on ENST00000301093; = p.A167P on NM_018260.3) | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2
- ZNF716 | c.1288C>A p.H430N | Missense Mutation (SNP) | VAF 57/308 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- ZNF804B | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ZNF850 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 71/225 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ZNF99 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZSCAN20 | c.3132G>T p.*1044Yext*53 | Nonstop Mutation (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- AC099489.1 | c.3342A>G p.T1114= | Silent (SNP) | VAF 24/116 reads (21%) | called by muse, mutect2, varscan2
- ADGRF3 | c.1803C>T p.F601= (on ENST00000311519 / NM_001145168.1; = p.F402= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/255 reads (13%) | catalogued as rs933057001, COSV61051678; called by muse, mutect2, varscan2
- ADO | c.93C>T p.S31= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs1475696093, COSV65677615, COSV65678074; called by muse, mutect2
- ADSS2 | c.714A>G p.L238= | Silent (SNP) | VAF 38/173 reads (22%) | catalogued as rs745448883; called by muse, mutect2, varscan2
- AHSG | c.18G>C p.L6= | Silent (SNP) | VAF 40/201 reads (20%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.2604G>T p.V868= | Silent (SNP) | VAF 84/315 reads (27%) | called by muse, mutect2, varscan2
- ALOX5 | c.1158G>A p.Q386= | Silent (SNP) | VAF 61/245 reads (25%) | called by muse, mutect2, varscan2
- AMER3 | c.612G>T p.P204= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as COSV100366045; called by muse, mutect2, varscan2
- ANKLE2 | c.1452A>G p.E484= | Silent (SNP) | VAF 22/55 reads (40%) | called by muse, mutect2, varscan2
- ANKRD26 | c.5112A>G p.L1704= | Silent (SNP) | VAF 30/128 reads (23%) | catalogued as rs1303977050; called by muse, mutect2, varscan2
- ARFGEF2 | c.894A>G p.T298= | Silent (SNP) | VAF 108/457 reads (24%) | called by muse, mutect2, varscan2
- ASAP1 | c.2079A>G p.K693= | Silent (SNP) | VAF 87/164 reads (53%) | called by muse, mutect2, varscan2
- ATP11A | c.120C>T p.Y40= | Silent (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- ATP8A2 | c.1062C>A p.T354= | Silent (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- BARHL2 | c.24G>T p.G8= | Silent (SNP) | VAF 55/313 reads (18%) | called by muse, mutect2, varscan2
- BEST3 | c.1344C>T p.P448= | Silent (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- BPI | c.891C>A p.A297= (on ENST00000262865; = p.A293= on NM_001725.3) | Silent (SNP) | VAF 35/169 reads (21%) | catalogued as rs767125785; called by muse, mutect2, varscan2
- BTBD6 | c.1311C>T p.D437= | Silent (SNP) | VAF 38/237 reads (16%) | catalogued as rs778312723; called by muse, mutect2, varscan2
- C1QB | c.675C>A p.T225= | Silent (SNP) | VAF 24/99 reads (24%) | called by muse, mutect2, varscan2
- CACNA1A | c.6285G>T p.R2095= | Silent (SNP) | VAF 33/116 reads (28%) | called by muse, mutect2, varscan2
- CCDC146 | c.141C>T p.F47= | Silent (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- CD93 | c.1245C>T p.Y415= | Silent (SNP) | VAF 32/191 reads (17%) | catalogued as rs762893959; called by muse, mutect2, varscan2
- CDH12 | c.27G>T p.L9= | Silent (SNP) | VAF 33/172 reads (19%) | called by muse, mutect2, varscan2
- CEL | c.2094G>T p.T698= (on ENST00000673714; = p.T695= on NM_001807.6) | Silent (SNP) | VAF 14/139 reads (10%) | called by muse, varscan2
- CEP85L | c.2250A>T p.I750= | Silent (SNP) | VAF 23/70 reads (33%) | called by muse, varscan2
- CNTN3 | c.1233A>G p.S411= | Silent (SNP) | VAF 13/140 reads (9%) | called by muse, mutect2
- CNTNAP1 | c.2550C>T p.F850= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs756084575, COSV52850086; called by muse, mutect2, varscan2
- CNTNAP4 | c.294G>T p.G98= | Silent (SNP) | VAF 54/193 reads (28%) | catalogued as COSV56680967; called by muse, mutect2, varscan2
- CNTNAP4 | c.891A>C p.A297= | Silent (SNP) | VAF 13/345 reads (4%) | catalogued as COSV56691174; called by muse, mutect2
- COL22A1 | c.2847G>T p.G949= | Silent (SNP) | VAF 94/259 reads (36%) | called by muse, mutect2, varscan2
- COL9A3 | c.693G>C p.R231= | Silent (SNP) | VAF 82/355 reads (23%) | called by muse, mutect2, varscan2
- CPLX3 | c.54G>T p.G18= | Silent (SNP) | VAF 27/239 reads (11%) | called by muse, mutect2, varscan2
- CRYAB | c.282G>A p.L94= | Silent (SNP) | VAF 86/430 reads (20%) | called by muse, mutect2, varscan2
- CSF1R | c.1734C>A p.P578= | Silent (SNP) | VAF 19/169 reads (11%) | called by muse, mutect2, varscan2
- CTXN2 | c.36G>A p.K12= | Silent (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- CYP4F3 | c.963A>G p.E321= | Silent (SNP) | VAF 36/164 reads (22%) | called by muse, mutect2, varscan2
- DBT | c.375A>G p.L125= | Silent (SNP) | VAF 10/79 reads (13%) | called by muse, mutect2, varscan2
- DENND4B | c.114G>T p.L38= | Silent (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- DIP2A | c.2667G>A p.V889= | Silent (SNP) | VAF 47/264 reads (18%) | called by muse, mutect2, varscan2
- DMRT2 | c.543C>A p.S181= | Silent (SNP) | VAF 26/112 reads (23%) | called by muse, mutect2, varscan2
- ELAVL4 | c.1102T>C p.L368= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs1166874815, COSV100836754; called by muse, mutect2, varscan2
- ELP1 | c.3655C>T p.L1219= | Silent (SNP) | VAF 53/350 reads (15%) | catalogued as rs950370236; called by muse, mutect2, varscan2
- ERGIC3 | c.474C>A p.T158= | Silent (SNP) | VAF 31/137 reads (23%) | called by muse, mutect2, varscan2
- ERICH3 | c.2379G>T p.G793= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV58610485; called by muse, mutect2, varscan2
- EXOC4 | c.2664G>T p.R888= | Silent (SNP) | VAF 39/105 reads (37%) | called by muse, mutect2, varscan2
- FAM81B | c.390A>G p.E130= | Silent (SNP) | VAF 51/258 reads (20%) | called by muse, mutect2, varscan2
- FECH | c.897G>T p.L299= | Silent (SNP) | VAF 84/415 reads (20%) | called by muse, mutect2, varscan2
- FEZF2 | c.663G>T p.L221= | Silent (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- FLG | c.6033C>T p.L2011= | Silent (SNP) | VAF 188/1653 reads (11%) | catalogued as rs749636062; called by muse, mutect2, varscan2
- FLG | c.4140T>A p.S1380= | Silent (SNP) | VAF 174/777 reads (22%) | called by muse, mutect2, varscan2
- GALNT1 | c.597G>T p.V199= | Silent (SNP) | VAF 35/271 reads (13%) | called by muse, mutect2, varscan2
- GBA3 | c.354C>A p.L118= | Silent (SNP) | VAF 21/187 reads (11%) | called by muse, mutect2, varscan2
- GDA | c.393A>G p.T131= | Silent (SNP) | VAF 13/117 reads (11%) | called by muse, mutect2
- GJB4 | c.370C>A p.R124= | Silent (SNP) | VAF 62/380 reads (16%) | catalogued as rs373126632, CM073102; called by muse, mutect2, varscan2
- GJC2 | c.954C>T p.C318= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as rs1250181465; called by muse, mutect2
- GLP2R | c.702C>A p.V234= | Silent (SNP) | VAF 30/169 reads (18%) | catalogued as COSV52328687; called by muse, mutect2, varscan2
- GNPTG | c.21G>A p.R7= | Silent (SNP) | VAF 50/118 reads (42%) | called by muse, varscan2
- GRAMD1B | c.1542G>T p.T514= | Silent (SNP) | VAF 20/250 reads (8%) | catalogued as rs772468231; called by muse, mutect2
- GRSF1 | c.207G>C p.G69= | Silent (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2, varscan2
- HFM1 | c.1857A>T p.G619= | Silent (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- HGSNAT | c.1656C>T p.F552= | Silent (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- HIVEP1 | c.4866C>T p.P1622= | Silent (SNP) | VAF 15/188 reads (8%) | catalogued as rs377350672; called by muse, mutect2
- HMCN1 | c.609A>G p.K203= | Silent (SNP) | VAF 22/342 reads (6%) | called by muse, mutect2
- HMX2 | c.540C>A p.A180= | Silent (SNP) | VAF 35/323 reads (11%) | catalogued as COSV60593273; called by muse, mutect2, varscan2
- HOXA9 | c.375C>A p.P125= | Silent (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
- IGHM | c.1192C>T p.L398= | Silent (SNP) | VAF 67/434 reads (15%) | called by muse, mutect2, varscan2
- IGKV1D-8 | c.42G>T p.L14= | Silent (SNP) | VAF 83/516 reads (16%) | called by muse, varscan2
- IGLV1-40 | c.234G>T p.G78= | Silent (SNP) | VAF 139/702 reads (20%) | catalogued as rs776641560; called by muse, mutect2, varscan2
- ITGAX | c.1614C>T p.D538= | Silent (SNP) | VAF 50/169 reads (30%) | catalogued as rs767382739; called by muse, mutect2, varscan2
- KCNK9 | c.765G>T p.R255= | Silent (SNP) | VAF 26/156 reads (17%) | called by muse, mutect2, varscan2
- KCNQ3 | c.2214A>T p.A738= | Silent (SNP) | VAF 52/274 reads (19%) | called by muse, mutect2, varscan2
- KCTD3 | c.987G>T p.L329= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- KIAA1614 | c.672T>A p.P224= | Silent (SNP) | VAF 20/164 reads (12%) | called by muse, mutect2, varscan2
- KLHL2 | c.513C>T p.T171= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as rs17852052; called by muse, mutect2, varscan2
- KPNA7 | c.31C>A p.R11= | Silent (SNP) | VAF 59/248 reads (24%) | called by muse, mutect2, varscan2
- KRT27 | c.330T>A p.A110= | Silent (SNP) | VAF 50/337 reads (15%) | called by muse, mutect2, varscan2
- KRTAP13-3 | c.102G>C p.L34= | Silent (SNP) | VAF 53/299 reads (18%) | called by muse, mutect2, varscan2
- LBR | c.96C>T p.S32= | Silent (SNP) | VAF 34/380 reads (9%) | called by muse, mutect2
- LMBR1 | c.93C>A p.L31= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV100626597; called by muse, mutect2, varscan2
- LRRC26 | c.492C>A p.G164= | Silent (SNP) | VAF 54/257 reads (21%) | called by muse, mutect2, varscan2
- LRRC9 | c.2370C>T p.L790= | Silent (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- LTBP1 | c.4275A>G p.A1425= (on ENST00000404816 / NM_206943.4; = p.A1099= on NM_000627.4) | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs752339161; called by muse, mutect2, varscan2
- MADCAM1 | c.918C>A p.I306= | Silent (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- MAP3K10 | c.2244G>T p.S748= | Silent (SNP) | VAF 35/221 reads (16%) | catalogued as rs1385448537; called by muse, mutect2, varscan2
- MAST1 | c.369C>T p.Y123= | Silent (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
- MEGF6 | c.3546G>T p.P1182= | Silent (SNP) | VAF 21/151 reads (14%) | called by muse, mutect2, varscan2
- MESP2 | c.33C>T p.L11= | Silent (SNP) | VAF 22/218 reads (10%) | called by muse, mutect2, varscan2
- MFN1 | c.1215G>T p.V405= | Silent (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2, varscan2
- MGARP | c.66G>C p.A22= | Silent (SNP) | VAF 36/386 reads (9%) | catalogued as rs746185035; called by muse, mutect2
- MGAT3 | c.1197C>T p.T399= | Silent (SNP) | VAF 9/267 reads (3%) | catalogued as rs1169149919, COSV100362019; called by muse, mutect2
- MMRN1 | c.492C>A p.G164= | Silent (SNP) | VAF 96/450 reads (21%) | called by muse, mutect2, varscan2
- MSANTD3 | c.93G>T p.V31= | Silent (SNP) | VAF 18/153 reads (12%) | catalogued as rs759041685; called by muse, mutect2, varscan2
- MUC16 | c.11628C>T p.T3876= | Silent (SNP) | VAF 18/83 reads (22%) | called by muse, mutect2, varscan2
- MUC17 | c.11577T>A p.A3859= | Silent (SNP) | VAF 31/226 reads (14%) | called by muse, mutect2, varscan2
- MUC3A | c.789C>T p.I263= | Silent (SNP) | VAF 39/373 reads (10%) | called by muse, mutect2, varscan2
- MYCN | c.882C>T p.V294= | Silent (SNP) | VAF 35/190 reads (18%) | called by muse, mutect2, varscan2
- MYH14 | c.3750G>T p.V1250= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs1310418241, COSV51827282; called by muse, mutect2, varscan2
- MYT1L | c.1446C>A p.S482= | Silent (SNP) | VAF 45/146 reads (31%) | called by muse, mutect2, varscan2
- NEU4 | c.63C>A p.T21= (on ENST00000391969 / NM_001167602.3; = p.T33= on NM_080741.4) | Silent (SNP) | VAF 36/263 reads (14%) | called by muse, mutect2, varscan2
- NISCH | c.3369G>C p.S1123= | Silent (SNP) | VAF 46/238 reads (19%) | called by muse, mutect2, varscan2
- NKX2-8 | c.330T>A p.S110= | Silent (SNP) | VAF 44/248 reads (18%) | called by muse, mutect2, varscan2
- NLGN4X | c.639C>G p.T213= | Silent (SNP) | VAF 33/152 reads (22%) | catalogued as COSV52032633, COSV99324549; called by muse, mutect2, varscan2
- NPB | c.174C>G p.P58= | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- NTN1 | c.549G>A p.K183= | Silent (SNP) | VAF 22/218 reads (10%) | catalogued as COSV51483395; called by muse, mutect2, varscan2
- NUP155 | c.1833T>A p.G611= (on ENST00000231498 / NM_153485.3; = p.G552= on NM_004298.4) | Silent (SNP) | VAF 32/323 reads (10%) | called by muse, mutect2
- NUP210 | c.3138C>T p.I1046= | Silent (SNP) | VAF 17/109 reads (16%) | called by muse, mutect2, varscan2
- NYAP2 | c.975C>A p.P325= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV55997999; called by muse, mutect2
- OPHN1 | c.2313C>T p.I771= | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as rs1336997066; called by muse, mutect2, varscan2
- OPN4 | c.576G>C p.L192= | Silent (SNP) | VAF 74/324 reads (23%) | called by muse, mutect2, varscan2
- OR10J3 | c.276C>T p.P92= | Silent (SNP) | VAF 116/402 reads (29%) | catalogued as COSV100171654; called by muse, mutect2, varscan2
- OR2M5 | c.231C>A p.T77= | Silent (SNP) | VAF 31/270 reads (11%) | catalogued as COSV100822777; called by muse, mutect2, varscan2
- OR2T34 | c.648C>A p.I216= | Silent (SNP) | VAF 16/556 reads (3%) | catalogued as COSV60901329; called by muse, mutect2
- OR2T6 | c.480C>G p.T160= | Silent (SNP) | VAF 10/165 reads (6%) | called by muse, mutect2
- OR4C15 | c.390C>T p.I130= (on ENST00000314644; = p.I76= on NM_001001920.2) | Silent (SNP) | VAF 31/126 reads (25%) | catalogued as COSV58955644; called by muse, mutect2, varscan2
- OR51L1 | c.228C>A p.S76= | Silent (SNP) | VAF 35/109 reads (32%) | called by muse, mutect2, varscan2
- OR6N2 | c.741G>C p.V247= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as rs139708565; called by muse, mutect2, varscan2
- OR8G2P | c.63A>T p.P21= | Silent (SNP) | VAF 44/200 reads (22%) | called by muse, mutect2, varscan2
- OVCH1 | c.1770G>T p.V590= | Silent (SNP) | VAF 102/250 reads (41%) | called by muse, mutect2, varscan2
- P3H3 | c.2031T>C p.P677= | Silent (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- PCDHA8 | c.1149G>A p.G383= | Silent (SNP) | VAF 51/347 reads (15%) | called by muse, mutect2, varscan2
- PCDHA9 | c.1467G>T p.L489= | Silent (SNP) | VAF 216/907 reads (24%) | called by muse, mutect2, varscan2
- PCDHB7 | c.813C>T p.T271= | Silent (SNP) | VAF 23/132 reads (17%) | catalogued as rs782760339; called by muse, mutect2, varscan2
- PDCD11 | c.4350G>T p.V1450= | Silent (SNP) | VAF 24/290 reads (8%) | called by muse, mutect2
- PGK2 | c.564C>T p.F188= | Silent (SNP) | VAF 17/208 reads (8%) | catalogued as rs1463664513, COSV59162664; called by muse, mutect2
- PGK2 | c.120C>A p.I40= | Silent (SNP) | VAF 36/182 reads (20%) | called by muse, mutect2, varscan2
- PIK3C2G | c.1017T>A p.S339= | Silent (SNP) | VAF 107/198 reads (54%) | called by muse, mutect2, varscan2
- PPARGC1B | c.1212G>A p.G404= | Silent (SNP) | VAF 30/194 reads (15%) | called by muse, mutect2, varscan2
- PROSER1 | c.2834G>A p.*945= | Silent (SNP) | VAF 9/113 reads (8%) | called by muse, mutect2
- PTN | c.129G>A p.K43= | Silent (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- PTPRT | c.3192C>A p.G1064= | Silent (SNP) | VAF 14/135 reads (10%) | called by muse, mutect2, varscan2
- REV3L | c.4266C>T p.C1422= | Silent (SNP) | VAF 38/117 reads (32%) | called by muse, mutect2, varscan2
- RFPL4AL1 | c.798C>A p.I266= | Silent (SNP) | VAF 68/700 reads (10%) | called by muse, mutect2, varscan2
- ROBO3 | c.3801G>A p.L1267= | Silent (SNP) | VAF 28/170 reads (16%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.1104A>T p.V368= (on ENST00000265814 / NM_001198628.1; = p.V341= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/316 reads (12%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.450C>A p.T150= (on ENST00000265814 / NM_001198628.1; = p.T123= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV56166408; called by muse, mutect2, varscan2
- S100A12 | c.159C>A p.V53= | Silent (SNP) | VAF 38/300 reads (13%) | called by muse, mutect2, varscan2
- SCARF2 | c.2244G>T p.A748= | Silent (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2
- SCN10A | c.1581T>G p.P527= | Silent (SNP) | VAF 17/161 reads (11%) | called by muse, mutect2
- SCN8A | c.2550A>T p.R850= | Silent (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- SCN9A | c.5656C>A p.R1886= (on ENST00000303354; = p.R1875= on NM_002977.3) | Silent (SNP) | VAF 35/225 reads (16%) | catalogued as COSV57599473; called by muse, mutect2, varscan2
- SEMA3D | c.2079G>A p.Q693= | Silent (SNP) | VAF 169/523 reads (32%) | called by muse, mutect2, varscan2
- SH3TC2 | c.3240T>A p.P1080= | Silent (SNP) | VAF 49/302 reads (16%) | called by muse, mutect2, varscan2
- SLAMF8 | c.756T>A p.S252= | Silent (SNP) | VAF 24/332 reads (7%) | catalogued as COSV56987768; called by muse, mutect2
- SLC26A11 | c.852G>C p.R284= | Silent (SNP) | VAF 40/131 reads (31%) | catalogued as rs1463620064; called by muse, mutect2, varscan2
- SLX4 | c.4869G>T p.A1623= | Silent (SNP) | VAF 41/121 reads (34%) | called by muse, mutect2, varscan2
- SNAP25 | c.252C>T p.F84= | Silent (SNP) | VAF 35/186 reads (19%) | catalogued as COSV54775202; called by muse, mutect2, varscan2
- SNX32 | c.249C>T p.L83= | Silent (SNP) | VAF 33/119 reads (28%) | called by muse, mutect2, varscan2
- SOX3 | c.1086A>G p.A362= | Silent (SNP) | VAF 6/50 reads (12%) | called by mutect2, varscan2
- SPAG17 | c.4245C>A p.T1415= | Silent (SNP) | VAF 24/228 reads (11%) | called by muse, mutect2
- SPINK5 | c.2514A>T p.T838= | Silent (SNP) | VAF 54/475 reads (11%) | catalogued as COSV56258019; called by muse, mutect2, varscan2
- SPTB | c.1461G>A p.E487= | Silent (SNP) | VAF 59/381 reads (15%) | called by muse, mutect2, varscan2
- STAG1 | c.1758A>G p.A586= | Silent (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- SUPT16H | c.1617A>T p.I539= | Silent (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- SYCN | c.102G>C p.G34= | Silent (SNP) | VAF 92/285 reads (32%) | catalogued as COSV100355894; called by muse, mutect2, varscan2
- TFF2 | c.312G>T p.R104= | Silent (SNP) | VAF 73/269 reads (27%) | called by muse, mutect2, varscan2
- TMEM132B | c.2769C>A p.A923= | Silent (SNP) | VAF 87/210 reads (41%) | called by muse, mutect2, varscan2
- TMEM151B | c.1044C>G p.L348= | Silent (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- TMEM232 | c.210A>T p.L70= | Silent (SNP) | VAF 43/126 reads (34%) | called by muse, mutect2, varscan2
- TMEM270 | c.9C>A p.A3= | Silent (SNP) | VAF 35/239 reads (15%) | called by muse, mutect2, varscan2
- TMEM81 | c.375A>T p.R125= | Silent (SNP) | VAF 68/206 reads (33%) | called by muse, mutect2, varscan2
- TRAPPC4 | c.474A>G p.L158= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as rs1303095294; called by muse, mutect2, varscan2
- TRIM63 | c.441G>T p.V147= | Silent (SNP) | VAF 16/116 reads (14%) | called by muse, mutect2, varscan2
- TSHZ2 | c.1605C>A p.A535= | Silent (SNP) | VAF 36/216 reads (17%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.3675G>C p.G1225= | Silent (SNP) | VAF 17/175 reads (10%) | called by muse, mutect2, varscan2
- UBIAD1 | c.621G>T p.V207= | Silent (SNP) | VAF 51/311 reads (16%) | called by muse, mutect2, varscan2
- UNC5C | c.2256C>T p.L752= | Silent (SNP) | VAF 24/146 reads (16%) | called by muse, mutect2, varscan2
- UQCRH | c.6A>G p.G2= | Silent (SNP) | VAF 21/184 reads (11%) | called by muse, mutect2, varscan2
- VPS13B | c.6972C>G p.V2324= | Silent (SNP) | VAF 10/267 reads (4%) | called by muse, mutect2
- WDR91 | c.915G>T p.T305= | Silent (SNP) | VAF 32/177 reads (18%) | called by muse, mutect2, varscan2
- WFIKKN2 | c.273C>A p.A91= | Silent (SNP) | VAF 26/172 reads (15%) | catalogued as COSV100259990; called by muse, mutect2, varscan2
- ZNF394 | c.1455T>C p.F485= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as rs1179644748; called by muse, mutect2, varscan2
- ZNF536 | c.3624C>T p.S1208= | Silent (SNP) | VAF 60/321 reads (19%) | called by muse, mutect2, varscan2
- ZNF639 | c.1227G>A p.G409= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs376347196; called by muse, mutect2, varscan2
- AC048338.2 | c.*325G>C | 3'UTR (SNP) | VAF 68/312 reads (22%) | catalogued as rs1280806774; called by muse, mutect2, varscan2
- AC135782.1 | n.349G>C | RNA (SNP) | VAF 101/290 reads (35%) | called by muse, mutect2, varscan2
- ADCY6 | c.3051+29G>A | Intron (SNP) | VAF 61/370 reads (16%) | called by muse, mutect2, varscan2
- AGXT | c.847-203C>A | Intron (SNP) | VAF 10/57 reads (18%) | catalogued as COSV56753338; called by muse, mutect2, varscan2
- AK7 | c.2134-343G>T | Intron (SNP) | VAF 19/55 reads (35%) | catalogued as rs1255807413; called by muse, mutect2, varscan2
- AKR1B1 | c.234+22G>A | Intron (SNP) | VAF 118/389 reads (30%) | catalogued as rs749448861; called by muse, mutect2, varscan2
- ANXA8L1 | c.21+66C>A | Intron (SNP) | VAF 84/287 reads (29%) | called by muse, mutect2, varscan2
- AOC4P | n.1597+87G>T | Intron (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498965 del A | 5'Flank (DEL) | VAF 33/147 reads (22%) | called by mutect2, pindel, varscan2
- ARHGAP11A | c.-2G>T | 5'UTR (SNP) | VAF 16/116 reads (14%) | catalogued as rs372331657; called by muse, mutect2
- ART3 | c.847+30C>A | Intron (SNP) | VAF 29/210 reads (14%) | catalogued as COSV100588024; called by muse, mutect2, varscan2
- ATP8B3 | c.1552+132A>T | Intron (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2, varscan2
- BNIP2 | c.-7G>A | 5'UTR (SNP) | VAF 10/93 reads (11%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29700295 C>A | 3'Flank (SNP) | VAF 37/528 reads (7%) | called by muse, mutect2
- C6orf201 | c.-435G>T | 5'UTR (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2
- CALHM6 | c.525+22C>A | Intron (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2
- CASP10 | c.685-3244C>T | Intron (SNP) | VAF 21/177 reads (12%) | catalogued as rs773609733; called by muse, mutect2, varscan2
- CCDC198 | c.656-4058C>A | Intron (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- CDCA5 | c.678+58G>C | Intron (SNP) | VAF 29/76 reads (38%) | catalogued as rs1297490479; called by muse, mutect2, varscan2
- CHRNA4 | c.*1164C>T | 3'UTR (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56811804 G>T | 3'Flank (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2
- CICP28 | chr7:56811921 G>T | 3'Flank (SNP) | VAF 28/345 reads (8%) | called by muse, mutect2
- CLK2P1 | n.567A>T | RNA (SNP) | VAF 55/355 reads (15%) | called by muse, mutect2, varscan2
- CSMD2 | c.8312-7419A>T | Intron (SNP) | VAF 28/152 reads (18%) | called by muse, mutect2, varscan2
- CTNNA2 | c.1057-79581G>T | Intron (SNP) | VAF 20/135 reads (15%) | called by muse, mutect2, varscan2
- DCAF17 | c.*452G>T | 3'UTR (SNP) | VAF 52/221 reads (24%) | called by muse, mutect2, varscan2
- DCHS2 | n.5514G>T | RNA (SNP) | VAF 25/165 reads (15%) | catalogued as rs1343829757; called by muse, mutect2, varscan2
- DHX40P1 | n.1006C>A | RNA (SNP) | VAF 72/280 reads (26%) | called by muse, mutect2, varscan2
- DOT1L | c.2806+264G>T | Intron (SNP) | VAF 72/224 reads (32%) | called by muse, mutect2, varscan2
- DPP6 | c.*247C>A | 3'UTR (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- EPSTI1 | chr13:42888454 G>A | 3'Flank (SNP) | VAF 21/167 reads (13%) | catalogued as rs769883623, COSV58047758; called by muse, mutect2, varscan2
57 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 57 other) are not listed here.
